Gene-level copy-number profile of tumor specimen TARGET-10-PATDDZ-09A from TARGET case TARGET-10-PATDDZ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.6 years (4,600 days).
Specimen TARGET-10-PATDDZ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.6aa13c53-2806-57e0-b82b-f2a586660e08.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PATDDZ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 370 have no estimate.
https://portal.gdc.cancer.gov/files/90ea3fbe-d98d-450d-8657-d4c468fc60f7

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,597; copy number 1: 1,098; copy number 2: 56,498; copy number 3: 10; copy number 4: 21; copy number 5: 2; copy number 6: 2; copy number 8: 25.

Homozygous deletions (total copy number 0; autosomes only): 216 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,906,757–90,190,681, 27 genes: IGKV3D-34, IGKV1D-33, IGKV1D-32, IGKV3D-31, IGKV2D-30, IGKV2D-29, IGKV2D-28, IGKV1D-27, IGKV2D-26, IGKV3D-25, IGKV2D-24, IGKV2D-23, IGKV1D-22, IGKV6D-21, IGKV3D-20, IGKV2D-19, IGKV2D-18, IGKV6D-41, IGKV1D-17, IGKV1D-16, IGKV3D-15, IGKV2D-14, IGKV1D-13, IGKV1D-12, IGKV3D-11, IGKV2D-10, IGKV1D-42.
- chr7:142,636,924–142,786,224, 19 genes: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1.
- chr9:21,160,235–25,678,440, 71 genes (broad region; genes not listed).
- chr14:21,924,063–22,530,378, 98 genes (broad region; genes not listed).
- chr21:30,089,717–30,097,836, 1 gene (within-gene range 0–2): AF096876.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 29 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,811,186–88,861,563, 1 gene, copy number 8 (within-gene range 2–8): AC244205.1.
- chr2:88,857,161–89,117,844, 24 genes, copy number 8: IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17.
- chr5:4,012,708–4,013,649, 1 gene, copy number 5: AC025773.1.
- chr7:20,377,331–20,377,401, 1 gene, copy number 6: AC004130.1.
- chr8:27,904,481–27,910,310, 1 gene, copy number 5 (within-gene range 2–5): AC069113.2.
- chr16:55,291,379–55,291,675, 1 gene, copy number 6: RN7SL841P.

Autosomal genes at a single copy (total copy number 1): 1,094. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
